Somatic mutation profile of tumor specimen TCGA-AA-3672-01A (aliquot TCGA-AA-3672-01A-01W-0900-09) from TCGA case TCGA-AA-3672, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage III; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AA-3672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d87d857d-d780-49a1-89a0-70e15b534ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3672-10A (Blood Derived Normal), aliquot TCGA-AA-3672-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c3240d2-fc45-4034-92ad-450df0cd5deb

The open-access MAF lists 2,114 somatic variants for this specimen: 1,618 protein-altering or splice-affecting, 443 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,079, Silent 443, Frame Shift Del 364, Nonsense Mutation 63, Frame Shift Ins 55, Splice Site 30, Intron 26, Splice Region 18, RNA 12, In Frame Del 5, 3'Flank 4, 3'UTR 4.

Variants (750 of 2,114; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ABCC6 | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs60791294, CM001041, CM014489, COSV99228202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 105/361 reads (29%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR2 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs1060502581, CD1513986, CM043449, COSV65807609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.3175del p.I1059* | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs62640570, CD073593; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFTR | c.3623del p.G1208Afs*3 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | catalogued as rs35396083; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CLCN4 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs879255583, COSV66465220; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.4474G>A p.G1492S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863223458, CM128980, COSV65665381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.6986del p.K2329Sfs*9 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs398124040, CD972168; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- GLDC | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386833542, CM061034, COSV58676669; ClinVar: likely pathogenic; called by muse, varscan2
- IDH2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 33/72 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267606870, CM106819, COSV57469615, COSV57472768; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MCCC2 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 61/187 reads (33%) | catalogued as rs763293192, COSV60157117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 56/141 reads (40%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- MYPN | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs71584501, CM086686, COSV62731748; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- NPHS1 | c.2515del p.Q839Rfs*8 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs386833918, CD097350, COSV100799747; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS2 | c.467del p.L156Cfs*25 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs528833893, CD042219; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 93/299 reads (31%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 21/36 reads (58%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- POGZ | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 78/224 reads (35%) | catalogued as rs886041669, COSV55032503; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438dup p.A147Cfs*28 | Frame Shift Ins (INS) | VAF 48/158 reads (30%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 40/64 reads (63%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- SUOX | c.363del p.P122Lfs*4 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | catalogued as rs1555198521, COSV99907216; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.3938G>A p.S1313N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100588496; called by muse, mutect2
- A2M | c.3207G>A p.W1069* | Nonsense Mutation (SNP) | VAF 72/149 reads (48%) | catalogued as COSV59383188; called by muse, mutect2, varscan2
- AAMDC | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs368865821; called by muse, mutect2, varscan2
- AARS2 | c.2611dup p.T871Nfs*21 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | catalogued as rs749666514; called by mutect2, varscan2
- ABCA13 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV70025990; called by muse, mutect2, varscan2
- ABCA6 | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.364); catalogued as COSV52635906; called by muse, mutect2, varscan2
- ABCB11 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1171209104, COSV55585715; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 11/16 reads (69%) | catalogued as rs777439793; called by mutect2, varscan2
- ABCC1 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.505); catalogued as rs200520366; called by muse, mutect2, varscan2
- ABCC1 | c.3956G>T p.G1319V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1567440452, COSV60680713; called by muse, mutect2, varscan2
- ABCC12 | c.1876C>A p.L626M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60911745; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC8 | c.2828T>A p.V943D | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV56846619; called by muse, mutect2, varscan2
- ABCD4 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100084070; called by muse, mutect2, varscan2
- ABCD4 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV53990903; called by muse, mutect2, varscan2
- ABHD15 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs371401765; called by muse, mutect2, varscan2
- ABHD16A | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.378); catalogued as COSV65442564; called by muse, mutect2, varscan2
- ABI3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV56799204; called by muse, mutect2, varscan2
- AC097636.1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs369862122; called by muse, mutect2, varscan2
- ACACA | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1223416494; called by muse, mutect2, varscan2
- ACAN | c.5489C>A p.T1830K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV61356428; called by muse, mutect2, varscan2
- ACAT1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99759116; called by muse, varscan2
- ACAT1 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768448235, COSV56186737; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 58/192 reads (30%) | catalogued as rs879396950, COSV52972585; called by mutect2, varscan2
- ACP2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779487060, COSV57037169, COSV57037429; called by muse, mutect2, varscan2
- ACRBP | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57523118; called by muse, mutect2, varscan2
- ACSBG2 | c.1578del p.I527Ffs*19 | Frame Shift Del (DEL) | VAF 36/119 reads (30%) | catalogued as rs754308951, COSV53122693; called by mutect2, pindel, varscan2
- ACTG2 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV61827573; called by muse, mutect2, varscan2
- ACTRT2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs776228150, COSV65758880; called by muse, mutect2, varscan2
- ACVR2A | c.263+1G>A p.X88_splice | Splice Site (SNP) | VAF 80/189 reads (42%) | catalogued as COSV99604020; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 109/180 reads (61%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM10 | c.1286A>G p.N429S | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53049398; called by muse, mutect2, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs782743337; called by mutect2, varscan2
- ADAMTS12 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs148311380; called by muse, mutect2, varscan2
- ADAMTS16 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765644208, COSV56978422, COSV56985832; called by muse, mutect2
- ADAMTS5 | c.1909A>G p.N637D | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53175887; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2498T>C p.V833A | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV99717321; called by muse, mutect2
- ADCY5 | c.3490T>C p.Y1164H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV59194433; called by muse, mutect2, varscan2
- ADGRG6 | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977070350, COSV51586987; called by muse, mutect2, varscan2
- ADGRL1 | c.489G>A p.W163* (on ENST00000340736 / NM_001008701.3; = p.W158* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61563676; called by muse, varscan2
- ADGRV1 | c.1204A>G p.R402G | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV67978962; called by muse, varscan2
- ADORA1 | c.564G>T p.W188C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as COSV55141421; called by muse, mutect2, varscan2
- ADRA1B | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV60700574; called by muse, mutect2, varscan2
- ADRA1D | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as COSV65240263, COSV65241036; called by muse, varscan2
- AFMID | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV100014842; called by muse, mutect2, varscan2
- AHNAK | c.14104G>A p.A4702T | Missense Mutation (SNP) | VAF 272/688 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV57204287; called by muse, mutect2, varscan2
- AHNAK | c.7220A>G p.D2407G | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV57204293; called by muse, mutect2, varscan2
- AHNAK2 | c.13170G>T p.K4390N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60908461; called by muse, mutect2, varscan2
- AHNAK2 | c.2875G>C p.V959L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.906); catalogued as COSV60908464; called by muse, mutect2, varscan2
- AKAP12 | c.3233A>G p.E1078G | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53570480; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62339245; called by muse, mutect2, varscan2
- AKNA | c.3502C>T p.R1168* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs765932672, COSV99799611, COSV99801305; called by muse, mutect2, varscan2
- AKT1S1 | c.488G>C p.G163A (on ENST00000344175 / NM_001098633.4; = p.G183A on NM_032375.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs754890149, COSV59274365; called by muse, mutect2, varscan2
- AL592490.1 | c.1707A>C p.Q569H | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV69424656, COSV69426927; called by muse, mutect2, varscan2
- ALCAM | c.1299A>G p.I433M | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV60245510, COSV60255607; called by muse, mutect2, varscan2
- ALDH1A2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.617); catalogued as COSV51078252; called by muse, mutect2, varscan2
- ALDH3B1 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50287919; called by muse, mutect2
- ALDOA | c.388G>T p.G130C (on ENST00000642816 / NM_001243177.4; = p.G76C on NM_184041.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57632022; called by muse, mutect2, varscan2
- ALG10B | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV58142372; called by muse, mutect2, varscan2
- ALG3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56610232; called by muse, mutect2, varscan2
- AMDHD1 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV57137804; called by muse, mutect2, varscan2
- AMER2 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as rs201439289, COSV63436065; called by muse, mutect2, varscan2
- AMHR2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.745); catalogued as rs369599312; called by muse, mutect2, varscan2
- AMPD1 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62415063, COSV62415300; called by muse, mutect2, varscan2
- ANAPC5 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV55841478; called by muse, mutect2, varscan2
- ANK1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs747776088, COSV55873534; called by muse, mutect2, varscan2
- ANK2 | c.6276A>G p.I2092M | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV52147208; called by muse, mutect2, varscan2
- ANK3 | c.8696C>T p.S2899F | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55045136; called by muse, mutect2, varscan2
- ANK3 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as COSV55045144; called by muse, mutect2, varscan2
- ANKFY1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284783260, COSV58914755; called by muse, mutect2
- ANKIB1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.278); catalogued as COSV56058735, COSV56058779; called by muse, mutect2, varscan2
- ANKRD44 | c.1723-1G>T p.X575_splice | Splice Site (SNP) | VAF 48/153 reads (31%) | catalogued as COSV99984282; called by muse, mutect2, varscan2
- ANKRD49 | c.258+13del | Splice Region (DEL) | VAF 74/149 reads (50%) | catalogued as rs750258320; called by mutect2, varscan2
- ANKRD55 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV61944454; called by muse, mutect2, varscan2
- ANKZF1 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768432915, COSV55475448; called by muse, mutect2, varscan2
- ANPEP | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV55589310; called by muse, mutect2, varscan2
- AOC2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as rs1243438892, COSV53824293; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as rs753029866; called by mutect2, varscan2
- AP2M1 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV53047123; called by muse, mutect2, varscan2
- AP4E1 | c.2605T>C p.Y869H | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV55915194; called by muse, mutect2, varscan2
- APBA2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs145494651; called by muse, mutect2, varscan2
- APBB1 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs748833409, COSV54972984; called by muse, mutect2, varscan2
- API5 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.376); catalogued as COSV66632486; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as rs3215969; called by mutect2, pindel
- ARFGAP1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs746166865, COSV62262379; called by muse, mutect2
- ARHGAP15 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs375193013; called by muse, mutect2, varscan2
- ARHGAP20 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52806107, COSV52806963; called by muse, mutect2, varscan2
- ARHGAP29 | c.1505A>T p.D502V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs775193842, COSV53108558; called by muse, mutect2, varscan2
- ARHGAP31 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as COSV51789373; called by muse, mutect2, varscan2
- ARHGAP35 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs199897795, COSV68329280; called by muse, mutect2, varscan2
- ARHGEF11 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs755443263, COSV63810478; called by muse, mutect2, varscan2
- ARHGEF15 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62724392; called by muse, mutect2, varscan2
- ARHGEF40 | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as COSV53878354; called by muse, mutect2, varscan2
- ARHGEF6 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51687675; called by muse, mutect2, varscan2
- ARID2 | c.925A>G p.N309D | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100535317, COSV57596504; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs776520069; called by mutect2, varscan2
- ARL13B | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV57396313; called by muse, mutect2, varscan2
- ARL15 | c.417A>G p.I139M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV72288930; called by muse, mutect2, varscan2
- ARMCX5 | c.1071T>G p.I357M | Missense Mutation (SNP) | VAF 19/574 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99863316; called by muse, mutect2
- ARNT | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV62229725; called by muse, mutect2, varscan2
- ARSA | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53349906; called by muse, mutect2, varscan2
- ARSB | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1285061397, COSV53719283; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs753865255; called by mutect2, varscan2
- ASB14 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67466931; called by muse, mutect2, varscan2
- ASF1B | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV54615473; called by muse, mutect2, varscan2
- ASTN1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.412); catalogued as COSV56061988; called by muse, mutect2, varscan2
- ASTN2 | c.2396+1G>A p.X799_splice (on ENST00000313400 / NM_001365069.1; = p.X748_splice on NM_014010.5) | Splice Site (SNP) | VAF 53/165 reads (32%) | catalogued as COSV100525197; called by muse, mutect2, varscan2
- ASXL1 | c.2113del p.E705Sfs*20 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs778670589, COSV60102287; called by mutect2, pindel, varscan2
- ASXL3 | c.3408G>T p.K1136N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52457965, COSV52466586; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs766479650; called by mutect2, pindel
- ATF7IP2 | c.2027G>T p.G676V | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1232504335, COSV100202526; called by muse, varscan2
- ATG4D | c.530del p.P177Lfs*75 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs776471163; called by mutect2, varscan2
- ATIC | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs149999349, COSV99378307; called by muse, mutect2, varscan2
- ATL1 | c.887del p.N296Tfs*2 | Frame Shift Del (DEL) | VAF 52/189 reads (28%) | catalogued as COSV63296322; called by mutect2, pindel, varscan2
- ATM | c.4208G>A p.S1403N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV99587778; called by muse, mutect2
- ATP10A | c.1801T>G p.S601A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV63513805; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP12A | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757041873, COSV54512643; called by muse, mutect2, varscan2
- ATP1A2 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63402358; called by muse, mutect2, varscan2
- ATP2A1 | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV62868546; called by muse, mutect2, varscan2
- ATP6V1H | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV62216977; called by muse, mutect2, varscan2
- ATP8A2 | c.2309A>C p.K770T | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV54938004; called by muse, mutect2, varscan2
- ATP8A2 | c.2642A>G p.Y881C | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54938012; called by muse, mutect2, varscan2
- ATP8B1 | c.2373del p.P792Hfs*8 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as rs1568184131, COSV99377078; called by mutect2, pindel, varscan2
- ATPAF1 | c.917T>C p.V306A (on ENST00000574428; = p.V329A on NM_022745.4) | Missense Mutation (SNP) | VAF 133/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61304434; called by muse, mutect2, varscan2
- ATXN2 | c.3247G>A p.A1083T (on ENST00000550104; = p.A923T on NM_002973.4) | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs759657946, COSV66481411; called by muse, mutect2, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs771612620; called by mutect2, varscan2
- ATXN3L | c.585del p.K195Nfs*2 | Frame Shift Del (DEL) | VAF 94/262 reads (36%) | catalogued as rs1411781059; called by mutect2, varscan2
- AURKC | c.313C>T p.R105C (on ENST00000302804 / NM_001015878.2; = p.R71C on NM_003160.3) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs756195705, COSV57137038; called by muse, mutect2, varscan2
- AUTS2 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776489400, COSV61384447; called by muse, mutect2, varscan2
- AVPR2 | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001640, CM983533, COSV61685792; called by muse, mutect2, varscan2
- B3GALT5 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs763079633, COSV58197968, COSV58199712; called by muse, mutect2, varscan2
- B3GNT7 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as rs776667326, COSV55005858; called by muse, varscan2
- B4GAT1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1018696626, COSV60819715; called by muse, mutect2, varscan2
- BAK1 | c.623T>A p.F208Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV62349355; called by muse, mutect2, varscan2
- BANP | c.694G>A p.A232T (on ENST00000286122; = p.A201T on NM_017869.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53733911; called by muse, mutect2, varscan2
- BARD1 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV53609005; called by muse, mutect2, varscan2
- BAX | c.265del p.R89Efs*44 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV53170202; called by mutect2, varscan2
- BCL6B | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53426377; called by muse, mutect2, varscan2
- BCOR | c.3449A>G p.E1150G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as rs373730020, COSV60700484; called by muse, mutect2, varscan2
- BCOR | c.1527G>T p.W509C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60700663; called by muse, mutect2, varscan2
- BDKRB2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs200683377; called by muse, mutect2, varscan2
- BFAR | c.1040T>A p.F347Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV55492578; called by muse, mutect2, varscan2
- BFSP2 | c.968A>G p.N323S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1559984117, COSV104404224, COSV56586463; called by muse, mutect2, varscan2
- BIN3 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs539144238, COSV52383199; called by muse, mutect2, varscan2
- BIRC6 | c.10706C>A p.P3569H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV70195727; called by muse, mutect2, varscan2
- BLK | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.616); catalogued as COSV52049599; called by muse, mutect2, varscan2
- BMP6 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51660879; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 73/140 reads (52%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD4 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99650028; called by muse, mutect2
- BRF1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs892408346, COSV59266107; called by muse, mutect2, varscan2
- BRINP1 | c.830A>C p.N277T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV56292560, COSV56297328; called by muse, mutect2, varscan2
- BSCL2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54014787; called by muse, mutect2, varscan2
- BTAF1 | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56430044; called by muse, mutect2, varscan2
- C15orf39 | c.580del p.V194Cfs*132 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs749135337, COSV100641311; called by mutect2, varscan2
- C1QTNF1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59260635; called by muse, mutect2, varscan2
- C1orf112 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199972566; called by muse, mutect2, varscan2
- C2orf49 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs765886202, COSV51527164; called by muse, mutect2, varscan2
- C3AR1 | c.712_714del p.S238del | In Frame Del (DEL) | VAF 50/418 reads (12%) | catalogued as rs772965450; called by mutect2, pindel, varscan2
- C5orf22 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs780737764, COSV57597490; called by muse, mutect2, varscan2
- C6 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384796748, COSV54705339; called by muse, mutect2, varscan2
- C9orf50 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV65252159; called by muse, varscan2
- C9orf85 | c.19A>G p.N7D | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58253578; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 55/165 reads (33%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CA6 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377435950; called by muse, mutect2, varscan2
- CABIN1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54077946; called by muse, mutect2, varscan2
- CACNA1E | c.3164G>A p.C1055Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1440901074, COSV62383091; called by muse, mutect2, varscan2
- CACNA1G | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61720503; called by muse, mutect2, varscan2
- CACNG3 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs780905732, COSV50064181; called by muse, mutect2, varscan2
- CAD | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | catalogued as rs771348417, COSV53023901; called by muse, mutect2, varscan2
- CALCA | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59027481; called by muse, mutect2, varscan2
- CAMKMT | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs201075899, COSV65923575; called by muse, mutect2, varscan2
- CAMKV | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV56554101; called by muse, mutect2, varscan2
- CAMTA2 | c.2435T>C p.L812P | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52776185; called by muse, mutect2, varscan2
- CAND2 | c.1648C>T p.R550W (on ENST00000456430 / NM_001162499.2; = p.R457W on NM_012298.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs753838369, COSV55986898; called by muse, mutect2, varscan2
- CAPZB | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); catalogued as rs770183245, COSV51644501; called by muse, mutect2, varscan2
- CARF | c.897del p.V300Sfs*55 | Frame Shift Del (DEL) | VAF 40/182 reads (22%) | catalogued as rs751635415; called by pindel, varscan2
- CARNMT1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV65193073; called by muse, mutect2, varscan2
- CARS2 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57284132; called by muse, mutect2, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel, varscan2
- CATSPERE | c.2224-2A>G p.X742_splice | Splice Site (SNP) | VAF 71/199 reads (36%) | catalogued as COSV100834953; called by muse, mutect2, varscan2
- CAVIN3 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.475); catalogued as COSV58268585; called by muse, mutect2, varscan2
- CCAR2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as rs778848959, COSV57904307; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC160 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs1448544224, COSV66251345; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs747131147; called by mutect2, pindel, varscan2
- CCDC74A | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV54605327; called by mutect2, varscan2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 32/112 reads (29%) | catalogued as rs768846308; called by mutect2, pindel, varscan2
- CCDC9B | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66874747; called by muse, mutect2, varscan2
- CCIN | c.1760G>T p.R587M | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV58724087; called by muse, mutect2, varscan2
- CCL23 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs142522197; called by muse, mutect2, varscan2
- CCPG1 | c.1559A>G p.E520G | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51241179; called by muse, mutect2, varscan2
- CD101 | c.1967del p.P656Rfs*10 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs769906221; called by mutect2, pindel, varscan2
- CD109 | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV54645579; called by muse, mutect2, varscan2
- CD180 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV56516898; called by muse, mutect2, varscan2
- CD247 | c.186del p.A63Rfs*15 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as COSV100758337; called by mutect2, pindel, varscan2
- CD27 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs144240256; called by muse, mutect2
- CD2AP | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63759339; called by muse, varscan2
- CD3G | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV52673760; called by muse, mutect2, varscan2
- CD55 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV58576598; called by muse, varscan2
- CD72 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs770122832, COSV52410274; called by muse, varscan2
- CDC45 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1568912348, COSV54243561; called by muse, mutect2, varscan2
- CDCA7L | c.1215del p.C406Vfs*46 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV100181107; called by mutect2, pindel, varscan2
- CDH10 | c.322dup p.T108Nfs*3 | Frame Shift Ins (INS) | VAF 39/135 reads (29%) | catalogued as rs748395403; called by mutect2, pindel, varscan2
- CDH24 | c.202C>T p.L68= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as COSV52973518; called by muse, mutect2, varscan2
- CDH26 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1277718478, COSV54842941; called by muse, mutect2, varscan2
- CDH8 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54849831; called by muse, mutect2, varscan2
- CDK13 | c.2699G>A p.C900Y | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51696549; called by muse, mutect2, varscan2
- CDK16 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.149); catalogued as COSV99331421, COSV99331480; called by muse, mutect2, varscan2
- CDK3 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as COSV56907636; called by muse, mutect2
- CDRT1 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs780172995, COSV63052457; called by muse, mutect2, varscan2
- CDYL2 | c.1178G>C p.C393S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV73653852, COSV73653875; called by muse, mutect2, varscan2
- CEACAM20 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57600870; called by muse, varscan2
- CECR2 | c.4118G>A p.R1373Q (on ENST00000342247 / NM_001290047.2; = p.R1189Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs966965861, COSV52836527; called by muse, mutect2, varscan2
- CELF2 | c.92A>G p.H31R (on ENST00000416382 / NM_001025077.3; = p.H38R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV59969856; called by muse, mutect2, varscan2
- CELSR2 | c.7877G>A p.R2626H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs201030395, COSV54767157; called by muse, mutect2, varscan2
- CENPJ | c.4002G>T p.M1334I | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV55034224; called by muse, mutect2, varscan2
- CENPU | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV55656493; called by muse, mutect2, varscan2
- CEP135 | c.699+2T>C p.X233_splice | Splice Site (SNP) | VAF 48/138 reads (35%) | catalogued as COSV99954187; called by muse, mutect2, varscan2
- CEP290 | c.4656del p.E1553Kfs*4 | Frame Shift Del (DEL) | VAF 85/210 reads (40%) | catalogued as rs62640572, CD062131; ClinVar: not provided; called by mutect2, pindel, varscan2
- CEP63 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765915059, COSV59674542; called by muse, mutect2, varscan2
- CERS3 | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV52565211; called by muse, mutect2, varscan2
- CERT1 | c.861G>T p.E287D (on ENST00000405807 / NM_001130105.1; = p.E159D on NM_005713.3) | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV54655751; called by muse, mutect2, varscan2
- CETP | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs1474311884, COSV52361565; called by muse, mutect2, varscan2
- CFAP126 | c.52T>C p.Y18H | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.861); catalogued as COSV61367520; called by muse, mutect2, varscan2
- CFAP43 | c.4031C>T p.A1344V | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs779066997, COSV63852055, COSV63854434; called by muse, mutect2, varscan2
- CFAP97 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777547282, COSV71712781, COSV71712782; called by muse, mutect2, varscan2
- CFAP97 | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57109242; called by muse, mutect2, varscan2
- CHAC1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV71435930; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD5 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs567329094, COSV52408139; called by muse, mutect2, varscan2
- CHD6 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as rs1259905601, COSV58554060; called by muse, mutect2, varscan2
- CHD6 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV58554068; called by muse, mutect2, varscan2
- CHD7 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165711448, CM1010229, COSV71107334; called by muse, mutect2, varscan2
- CHL1 | c.2686A>G p.N896D (on ENST00000397491 / NM_001253387.1; = p.N912D on NM_006614.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587034; called by muse, mutect2, varscan2
- CHML | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 54/187 reads (29%) | catalogued as rs1558447772; called by mutect2, pindel, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRDL1 | c.1027del p.V343Cfs*16 (on ENST00000372045; = p.V349Cfs*16 on NM_145234.4) | Frame Shift Del (DEL) | VAF 81/273 reads (30%) | catalogued as COSV54322924; called by mutect2, pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST12 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51673909; called by muse, mutect2, varscan2
- CHSY1 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs373782542; called by muse, mutect2, varscan2
- CIAPIN1 | c.557-2A>G p.X186_splice | Splice Site (SNP) | VAF 39/119 reads (33%) | catalogued as COSV101275864; called by muse, mutect2, varscan2
- CIB3 | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs767528190, COSV54165469, COSV99521974; called by muse, mutect2, varscan2
- CIT | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 157/617 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55860625; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/172 reads (30%) | catalogued as rs761731080; called by mutect2, varscan2
- CLASP2 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV56276478; called by muse, varscan2
- CLCA2 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs781089415, COSV65286170; called by muse, mutect2, varscan2
- CLCN1 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV58367587; called by muse, mutect2, varscan2
- CLCN3 | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372151295, COSV61626345; called by muse, mutect2, varscan2
- CLCN4 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV66465228; called by muse, mutect2, varscan2
- CLPB | c.1937del p.G646Afs*86 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as CM150846; called by mutect2, varscan2
- CLPX | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55643316; called by muse, mutect2, varscan2
- CLSTN1 | c.2327G>T p.R776L (on ENST00000377298 / NM_001009566.3; = p.R766L on NM_014944.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63646677, COSV63648317; called by muse, mutect2, varscan2
- CLU | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.503); catalogued as rs771208664, COSV57065706; called by muse, mutect2, varscan2
- CLYBL | c.946G>T p.G316W | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184746, COSV59217305; called by muse, mutect2, varscan2
- CMAS | c.760T>C p.W254R | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57556036; called by muse, mutect2, varscan2
- CMTR1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV65089536; called by muse, mutect2
- CMYA5 | c.5468del p.K1823Rfs*17 | Frame Shift Del (DEL) | VAF 130/400 reads (33%) | catalogued as rs954878355; called by mutect2, pindel, varscan2
- CNGA3 | c.1382del p.P461Qfs*4 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as COSV55626507, COSV99736093; called by mutect2, pindel, varscan2
- CNOT1 | c.1451T>G p.L484R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57764897; called by muse, mutect2, varscan2
- CNOT6 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs867009011, COSV56159377; called by muse, mutect2, varscan2
- CNOT8 | c.353A>T p.N118I | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV53585028; called by muse, mutect2, varscan2
- CNR1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs764560714, COSV62986478; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | catalogued as rs761011518, COSV99078405; called by mutect2, varscan2
- CNTN2 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59348270; called by muse, mutect2, varscan2
- CNTN3 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1016109917, COSV55163762; called by muse, mutect2, varscan2
- COL11A1 | c.4777A>C p.M1593L | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.159); catalogued as COSV62173691; called by muse, mutect2
- COL12A1 | c.5394+2T>C p.X1798_splice | Splice Site (SNP) | VAF 31/61 reads (51%) | catalogued as COSV100485499; called by muse, mutect2, varscan2
- COL19A1 | c.589A>C p.T197P | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV59565828; called by muse, mutect2, varscan2
- COL19A1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV59565836; called by muse, mutect2, varscan2
- COL24A1 | c.4230A>C p.E1410D | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as COSV65302287; called by muse, mutect2, varscan2
- COL4A1 | c.4249+1G>A p.X1417_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as rs760532152, COSV101010988; called by muse, mutect2, varscan2
- COL4A1 | c.4006G>A p.V1336I | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs202209298; called by muse, mutect2, varscan2
- COL4A2 | c.4196T>C p.V1399A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV64625076; called by mutect2, varscan2
- COL4A6 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV57859703; called by muse, mutect2, varscan2
- COL4A6 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 75/212 reads (35%) | catalogued as COSV57859710; called by muse, mutect2, varscan2
- COL6A3 | c.5311del p.V1771Sfs*8 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as COSV55082747; called by mutect2, pindel, varscan2
- COL7A1 | c.8223G>T p.Q2741H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56476037; called by muse, mutect2, varscan2
- COX10 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55402437; called by muse, varscan2
- CPED1 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV59997510; called by muse, mutect2, varscan2
- CPNE9 | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56067712; called by muse, mutect2, varscan2
- CPS1 | c.3698C>A p.A1233D | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV51802617; called by muse, mutect2, varscan2
- CPSF1 | c.1605G>A p.M535I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV62938989; called by muse, mutect2, varscan2
- CPSF6 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1223225367, COSV57012354; called by muse, mutect2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV51715473; called by mutect2, varscan2
- CRAT | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1554725925; called by muse, mutect2, varscan2
- CREBBP | c.6215G>A p.R2072Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as rs1476634343, COSV52114650; called by muse, mutect2, varscan2
- CREBRF | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV51631360; called by muse, mutect2, varscan2
- CRY1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs749506981, COSV50481097; called by muse, mutect2, varscan2
- CRY1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs1328030847, COSV50481104; called by muse, mutect2, varscan2
- CRYBG1 | c.5212G>A p.G1738R | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64810816; called by muse, mutect2, varscan2
- CRYBG3 | c.7688G>A p.R2563Q | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs371125970; called by muse, mutect2, varscan2
- CSF2RB | c.2048T>C p.V683A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV53255662; called by muse, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 41/167 reads (25%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD2 | c.5561A>G p.D1854G | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53882178; called by muse, mutect2, varscan2
- CSMD2 | c.4327+1G>A p.X1443_splice | Splice Site (SNP) | VAF 45/128 reads (35%) | catalogued as COSV99586859; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 48/158 reads (30%) | catalogued as rs369743261; called by mutect2, varscan2
- CTNNA2 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100786127, COSV63548356; called by muse, varscan2
- CTR9 | c.1285-1G>T p.X429_splice | Splice Site (SNP) | VAF 60/185 reads (32%) | catalogued as COSV100797274; called by muse, mutect2, varscan2
- CTSH | c.526T>C p.F176L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54984220; called by muse, mutect2, varscan2
- CUBN | c.8232G>T p.W2744C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV64708356; called by muse, mutect2, varscan2
- CUL4B | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV60684842; called by muse, mutect2, varscan2
- CUL9 | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755755698, COSV52725573; called by muse, mutect2, varscan2
- CUL9 | c.3248T>C p.I1083T | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52725583; called by muse, mutect2, varscan2
- CUL9 | c.5320G>A p.V1774M | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as rs769189873, COSV52725595; called by muse, mutect2, varscan2
- CUL9 | c.5648A>G p.H1883R | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV99334892; called by muse, mutect2
- CUX1 | c.2905A>G p.K969E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52891744; called by muse, mutect2, varscan2
- CUX2 | c.3634G>A p.V1212I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs764440579, COSV55625051; called by muse, mutect2, varscan2
- CXADR | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV53027936; called by muse, mutect2, varscan2
- CYBC1 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1020570929, COSV60062900; called by muse, mutect2, varscan2
- CYP11B1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs148066255; called by muse, mutect2, varscan2
- CYP20A1 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61909036; called by muse, mutect2, varscan2
- CYP39A1 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as COSV51494631; called by muse, mutect2, varscan2
- CYP4F12 | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV61172428; called by muse, varscan2
- CYP4F22 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54106617; called by muse, mutect2, varscan2
- CYREN | c.96del p.K33Rfs*3 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs1187040493; called by mutect2, pindel, varscan2
- CYSLTR1 | c.657del p.K219Nfs*3 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | catalogued as rs35745545; called by mutect2, pindel, varscan2
- DAAM2 | c.3085G>C p.A1029P (on ENST00000274867 / NM_001201427.2; = p.A1028P on NM_015345.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51302828; called by muse, mutect2, varscan2
- DAPK1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV63784495; called by muse, mutect2, varscan2
- DCAF17 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64544603, COSV64545828; called by muse, mutect2, varscan2
- DCAF7 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV60406710; called by muse, mutect2, varscan2
- DCDC2 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV65828328; called by muse, mutect2, varscan2
- DCLK3 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.152); catalogued as COSV69362258; called by muse, mutect2, varscan2
- DCP2 | c.555A>C p.K185N | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV66616165; called by muse, mutect2, varscan2
- DCST2 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV55050150; called by muse, mutect2, varscan2
- DCST2 | c.1673T>C p.L558P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55050157; called by muse, mutect2, varscan2
- DCX | c.1007C>T p.T336M (on ENST00000636035 / NM_001195553.2; = p.T331M on NM_000555.3) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs780314121, COSV57566148; called by muse, mutect2, varscan2
- DDR1 | c.2308C>T p.R770W (on ENST00000324771; = p.R733W on NM_001954.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368543890; called by muse, mutect2, varscan2
- DDX19A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV56358856; called by muse, mutect2, varscan2
- DDX42 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63789365; called by muse, mutect2, varscan2
- DDX52 | c.1667T>C p.M556T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs990878142; called by muse, mutect2, varscan2
- DDX54 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1397446061, COSV58372076; called by muse, mutect2, varscan2
- DDX54 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58372096; called by muse, mutect2, varscan2
- DENND4C | c.3067C>T p.P1023S (on ENST00000434457 / NM_001330640.2; = p.P974S on NM_017925.7) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs753295343, COSV63008397; called by muse, mutect2, varscan2
- DGCR2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs777281857, COSV54216564; called by muse, mutect2
- DHX16 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64579811; called by muse, mutect2, varscan2
- DHX57 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV54882599; called by muse, mutect2, varscan2
- DIP2B | c.2731G>T p.G911* | Nonsense Mutation (SNP) | VAF 34/158 reads (22%) | catalogued as COSV56579169, COSV56590650; called by muse, mutect2, varscan2
- DISC1 | c.2405G>T p.S802I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV64091397; called by muse, mutect2, varscan2
- DKK2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761402051, COSV53394372; called by muse, mutect2, varscan2
- DLG2 | c.1783del p.V595Sfs*16 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | catalogued as COSV54635659, COSV54652999; called by mutect2, pindel, varscan2
- DLG2 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs577146407, COSV54620091, COSV54622530; called by muse, mutect2, varscan2
- DLG5 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1564537652, COSV64946853; called by muse, mutect2, varscan2
- DLGAP4 | c.1838A>C p.D613A | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59414613; called by muse, mutect2, varscan2
- DMD | c.9584G>A p.R3195H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756958090, COSV58892970, COSV58926071; called by muse, mutect2, varscan2
- DMTF1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs199931097, COSV100487549, COSV58683312; called by muse, mutect2, varscan2
- DMTN | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99741478; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 56/145 reads (39%) | catalogued as COSV57576404; called by muse, mutect2, varscan2
- DNAAF4 | c.430del p.I144* | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs755135568; called by mutect2, pindel, varscan2
- DNAH11 | c.4643G>T p.S1548I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs199538599, COSV60941119; called by muse, mutect2, varscan2
- DNAH11 | c.8269G>T p.D2757Y | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV60941125; called by muse, mutect2, varscan2
- DNAH17 | c.4190T>C p.V1397A | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67750022; called by muse, mutect2, varscan2
- DNAH2 | c.3640C>T p.Q1214* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV66716640; called by muse, mutect2, varscan2
- DNAH8 | c.6695G>A p.R2232H | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59426561; called by muse, mutect2, varscan2
- DNMBP | c.2582A>G p.E861G | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as COSV60620843; called by muse, mutect2, varscan2
- DOCK10 | c.1721G>T p.R574I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV51349180; called by muse, mutect2, varscan2
- DOP1A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765139261, COSV52707072; called by muse, mutect2, varscan2
- DOT1L | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV67108163; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | catalogued as rs35482889; called by mutect2, varscan2
- DPY30 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.421); catalogued as COSV54458670; called by muse, mutect2, varscan2
- DROSHA | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.969); catalogued as COSV60772740; called by muse, mutect2, varscan2
- DSC3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757290041, COSV64571675; called by muse, mutect2
- DSCAM | c.4103A>G p.D1368G | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV101259288; called by muse, mutect2
- DSEL | c.2402G>A p.W801* | Nonsense Mutation (SNP) | VAF 59/204 reads (29%) | catalogued as COSV59489563; called by muse, mutect2, varscan2
- DSP | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV65791315; called by muse, mutect2, varscan2
- DST | c.15845G>A p.R5282H (on ENST00000361203 / NM_001374722.1; = p.R2870H on NM_015548.5) | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.629); catalogued as rs754436072, COSV54998919; called by muse, mutect2, varscan2
- DST | c.6917C>A p.P2306H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV99751939; called by muse, mutect2, varscan2
- DST | c.1267C>T p.Q423* (on ENST00000361203 / NM_001374722.1; = p.Q97* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV54998940; called by muse, mutect2, varscan2
- DTX4 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as rs1025103416, COSV57088503; called by muse, mutect2, varscan2
- DYNAP | c.550G>T p.A184S (on ENST00000321600; = p.A158S on NM_173629.3) | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV58666018, COSV58666862; called by muse, mutect2, varscan2
- DYSF | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775370021, COSV50269980; called by muse, mutect2, varscan2
- DYSF | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs573666770, COSV50266434; called by muse, mutect2
- E2F7 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 144/269 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377645692; called by muse, mutect2, varscan2
- E2F8 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV51462036; called by muse, mutect2, varscan2
- ECHDC2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768996501, COSV64300190; called by muse, mutect2, varscan2
- ECT2L | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV62882814; called by muse, mutect2, varscan2
- EDC4 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV62765429; called by muse, mutect2, varscan2
- EFEMP1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV62615078; called by muse, varscan2
- EFNB1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs367996552, COSV52661024, COSV52662951; called by muse, mutect2, varscan2
- EFR3A | c.2160T>C p.V720= | Splice Region (SNP) | VAF 17/154 reads (11%) | catalogued as COSV54453416; called by muse, mutect2, varscan2
- EGFL6 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 68/219 reads (31%) | catalogued as COSV63632888; called by muse, mutect2, varscan2
- EGR2 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54346153; called by muse, mutect2, varscan2
- EHD3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs780938047, COSV59029333; called by muse, mutect2, varscan2
- EHMT1 | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs371824384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF3B | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs766601514, COSV62802730; called by muse, mutect2, varscan2
- EIF4E1B | c.158del p.G53Afs*110 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs751393132, COSV53781968; called by mutect2, varscan2
- ELAPOR1 | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884411; called by muse, mutect2
- ELAPOR2 | c.1541C>T p.T514I (on ENST00000450689 / NM_001142749.3; = p.T347I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1562921400, COSV51884220; called by muse, mutect2, varscan2
- ELF2 | c.857T>C p.V286A (on ENST00000379550 / NM_001331036.2; = p.V226A on NM_006874.4) | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as COSV55491730; called by muse, mutect2, varscan2
- EMG1 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV54641095; called by muse, mutect2, varscan2
- EML3 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53870511; called by muse, mutect2, varscan2
- EMSY | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58257563; called by muse, mutect2, varscan2
- ENAM | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs143134915; called by muse, varscan2
- ENDOU | c.49T>A p.W17R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.735); catalogued as COSV57464567; called by muse, mutect2, varscan2
- EOGT | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.092); catalogued as COSV55149473; called by muse, mutect2, varscan2
- EP400 | c.7016C>T p.A2339V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1322226889, COSV57763527; called by muse, mutect2, varscan2
- EPB41L3 | c.3061C>T p.H1021Y | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59445135; called by muse, mutect2, varscan2
- EPB41L3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376210046, COSV59445161; called by muse, mutect2, varscan2
- EPHA8 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV51262942; called by muse, mutect2, varscan2
- EPM2AIP1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV51614584; called by muse, mutect2, varscan2
- EPX | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs573827983, COSV56595010; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 60/148 reads (41%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBB3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1354914975, COSV57247317; called by muse, mutect2, varscan2
- ERMAP | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60273469; called by muse, mutect2, varscan2
- ESRRA | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50004636; called by muse, mutect2
- ESYT2 | c.2627A>G p.N876S (on ENST00000613624; = p.N800S on NM_020728.3) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV51747897; called by muse, mutect2
- ETF1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62126896; called by muse, mutect2, varscan2
- EVC2 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1238592664, COSV60388197; called by muse, mutect2, varscan2
- EXO1 | c.2446C>A p.P816T | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62216448, COSV62217167; called by muse, mutect2, varscan2
- EZH2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs377467108; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- F2RL2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs150312521; called by muse, mutect2, varscan2
- F5 | c.6641T>C p.L2214P | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63120860; called by muse, mutect2, varscan2
- FA2H | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV54725293; called by muse, mutect2, varscan2
- FABP6 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV67436704; called by muse, mutect2, varscan2
- FAM133A | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.991); catalogued as COSV59073809; called by muse, mutect2, varscan2
- FAM135B | c.3793T>C p.L1265= | Splice Region (SNP) | VAF 42/134 reads (31%) | catalogued as COSV52706554, COSV99417277; called by muse, mutect2, varscan2
- FAM167A | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV52667726; called by muse, mutect2, varscan2
- FAM189B | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs1454161033, COSV63218795; called by muse, varscan2
- FAM71A | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs535062338, COSV54234649; called by muse, mutect2, varscan2
- FAM71B | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs372740796, COSV57227573; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT2 | c.7130del p.P2377Qfs*41 | Frame Shift Del (DEL) | VAF 46/165 reads (28%) | catalogued as rs1199962794; called by mutect2, pindel, varscan2
- FAT2 | c.6907C>T p.R2303W | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs201714112; called by muse, mutect2, varscan2
- FAT4 | c.10138T>G p.F3380V | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.087); catalogued as COSV58672422; called by muse, mutect2, varscan2
- FAT4 | c.10667C>A p.A3556D | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.999); catalogued as COSV58672436; called by muse, mutect2, varscan2
- FAT4 | c.13832C>T p.P4611L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100627407; called by muse, mutect2, varscan2
- FBL | c.206A>T p.N69I | Missense Mutation (SNP) | VAF 164/500 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55681956; called by muse, mutect2, varscan2
- FBN1 | c.1735A>G p.R579G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV57309919; called by muse, mutect2, varscan2
- FBXO10 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52831510; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO24 | c.1528C>T p.Q510* (on ENST00000241071 / NM_033506.3; = p.Q548* on NM_012172.5) | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as COSV53823712; called by muse, mutect2, varscan2
- FBXO3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs138194845; called by muse, mutect2, varscan2
- FBXO32 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs370398489; called by muse, mutect2, varscan2
- FBXO34 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV58253420; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FCRL6 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58940026; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 72/252 reads (29%) | catalogued as rs748969702; called by mutect2, varscan2
- FHOD1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV50758674; called by muse, mutect2, varscan2
- FKBP15 | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs769709985, COSV53032077; called by muse, mutect2, varscan2
- FKBP15 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.702); catalogued as COSV53032096; called by muse, mutect2, varscan2
- FLNC | c.3422C>T p.P1141L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008133219, COSV57950856, COSV57956561; called by muse, mutect2, varscan2
- FLRT2 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV58136661; called by muse, mutect2, varscan2
- FMR1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV54421945; called by muse, mutect2, varscan2
- FOLR3 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs761906150, COSV61529831; called by muse, mutect2, varscan2
- FOSL2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53103433; called by muse, mutect2, varscan2
- FOXG1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57395324; called by muse, mutect2, varscan2
- FOXN1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769969790, COSV56880586, COSV56882002; called by muse, mutect2, varscan2
- FOXN3 | c.1397T>C p.I466T (on ENST00000261302; = p.I444T on NM_005197.4) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99725904; called by muse, mutect2
- FOXO4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1418356959, COSV58575215; called by muse, varscan2
- FPGT-TNNI3K | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV58546281; called by muse, mutect2, varscan2
- FRAS1 | c.11019G>T p.K3673N | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53591190; called by muse, mutect2, varscan2
- FRAS1 | c.11239G>T p.G3747W | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53591204; called by muse, mutect2, varscan2
- FREM1 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66518165; called by muse, mutect2, varscan2
- FREM2 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs780054707, COSV54829338; called by muse, mutect2, varscan2
- FRMD4A | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs747029408, COSV62264394; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs752351689; called by mutect2, pindel, varscan2
- FSTL5 | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60182527; called by muse, mutect2, varscan2
- GABPA | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs2829897; called by muse, mutect2, varscan2
- GABRA5 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV59476077; called by muse, mutect2
- GABRB3 | c.700T>A p.S234T | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV54651269; called by muse, mutect2, varscan2
- GAN | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 108/344 reads (31%) | catalogued as rs370358470, CM002982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs758551787; called by mutect2, varscan2
- GASK1B | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV56704736; called by muse, mutect2, varscan2
- GATB | c.1384A>C p.T462P | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as COSV56128938; called by muse, mutect2, varscan2
- GBA3 | c.1251G>A p.W417* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs778733949, COSV72437861; called by muse, mutect2, varscan2
- GCNT1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.104); catalogued as COSV65056913; called by muse, mutect2, varscan2
- GCNT1 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65056918; called by muse, mutect2, varscan2
- GDF11 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV57689281; called by muse, mutect2, varscan2
- GDF9 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 51/166 reads (31%) | catalogued as rs770828556, COSV51525809; called by muse, mutect2, varscan2
- GIGYF2 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 209/764 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1361124254, COSV65246799; called by muse, mutect2, varscan2
- GIN1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs782158464, COSV67535957; called by muse, mutect2, varscan2
- GJB1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM101169, COSV62139531; called by muse, mutect2, varscan2
- GLB1L2 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60277497; called by muse, mutect2, varscan2
- GLI3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.244); catalogued as rs775586921, COSV67885468; called by muse, mutect2, varscan2
- GLIS3 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs146067479, COSV60924265; called by muse, mutect2, varscan2
- GLUD1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1471790434, COSV53277528; called by muse, mutect2, varscan2
- GNPTAB | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 94/360 reads (26%) | catalogued as COSV54777018; called by muse, mutect2, varscan2
- GOLGA4 | c.75G>A p.A25= | Splice Region (SNP) | VAF 13/63 reads (21%) | catalogued as rs201354584, COSV62709319, COSV62710637; called by muse, mutect2, varscan2
- GOLGA7 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV63298990; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 54/165 reads (33%) | catalogued as rs370114090; called by mutect2, varscan2
- GOT2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs754471368, COSV55330794; called by muse, mutect2, varscan2
- GP5 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as rs747330061, COSV59877770; called by muse, varscan2
- GPC4 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63696924; called by muse, mutect2, varscan2
- GPCPD1 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.804); catalogued as rs1490591594, COSV66830185; called by muse, mutect2, varscan2
- GPD2 | c.1608G>T p.E536D | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1421758586, COSV100132993; called by muse, mutect2
- GPNMB | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs145407985; called by muse, mutect2, varscan2
- GPR12 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67344059; called by muse, mutect2, varscan2
- GPR161 | c.1214T>C p.M405T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54787891; called by muse, mutect2, varscan2
- GPR162 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50589153; called by muse, mutect2, varscan2
- GPR183 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.905); catalogued as COSV63117065; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 74/276 reads (27%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR50 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV54437147; called by muse, mutect2, varscan2
- GPRC6A | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV59951635; called by muse, mutect2, varscan2
- GREB1 | c.3476G>T p.R1159M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as COSV52181238; called by muse, mutect2, varscan2
- GRID1 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.657); catalogued as COSV60014174; called by muse, mutect2
- GRIN2A | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58021215; called by muse, mutect2, varscan2
- GRK1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755707527, COSV59553806; called by muse, mutect2, varscan2
- GRM1 | c.3044del p.P1015Lfs*16 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | catalogued as rs1288762112, CM122919; called by mutect2, pindel, varscan2
- GRM4 | c.2599G>A p.A867T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV65210834; called by muse, mutect2, varscan2
- GRM4 | c.2088del p.A697Pfs*126 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as COSV65211916; called by mutect2, pindel, varscan2
- GRN | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs529849967, CM099945, COSV50006207; called by muse, mutect2, varscan2
- GSTM3 | c.467del p.K156Sfs*30 | Frame Shift Del (DEL) | VAF 71/246 reads (29%) | catalogued as rs59389091; called by mutect2, pindel, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTF3C5 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV59598919; called by muse, mutect2
- GTPBP4 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as rs1171347091, COSV62550179, COSV62552041; called by muse, mutect2, varscan2
- GTSF1L | c.363del p.P122Lfs*50 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | catalogued as rs1568892529; called by mutect2, varscan2
- GUCA2B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs140898399; called by muse, mutect2, varscan2
- GUCY2C | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99663305; called by muse, mutect2
- GXYLT1 | c.495C>G p.N165K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs778789994, COSV99787924; called by muse, varscan2
- GYG2 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs778297940, COSV58549231; called by muse, mutect2, varscan2
- H2BC17 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV58152038; called by muse, mutect2, varscan2
- H2BC7 | c.38del p.K13Rfs*7 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs1561982611; called by mutect2, pindel, varscan2
- HAPLN3 | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61356432; called by muse, mutect2, varscan2
- HAT1 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV51361879; called by muse, mutect2, varscan2
- HAUS8 | c.1201T>C p.S401P | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as COSV99505140; called by muse, varscan2
- HEATR4 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV58570003, COSV58570018; called by muse, mutect2, varscan2
- HECW2 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1446047038, COSV53650179; called by muse, mutect2, varscan2
- HELB | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs139082430, COSV56072243; called by mutect2, varscan2
- HIVEP2 | c.5843T>G p.V1948G | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99171541; called by muse, mutect2
- HIVEP3 | c.2009A>G p.Q670R | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); catalogued as COSV56010080; called by muse, mutect2, varscan2
- HLA-C | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66110777; called by muse, mutect2, varscan2
- HLA-E | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV64927241; called by muse, mutect2, varscan2
- HMCN1 | c.6308C>T p.P2103L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs768441829, COSV54878232; called by muse, mutect2, varscan2
- HNF4G | c.496G>A p.D166N (on ENST00000354370 / NM_001330561.2; = p.D213N on NM_004133.5) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs766767221, COSV62965953; called by muse, mutect2, varscan2
- HNF4G | c.763G>A p.D255N (on ENST00000354370 / NM_001330561.2; = p.D302N on NM_004133.5) | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs755923251, COSV62965958, COSV62972686; called by muse, mutect2, varscan2
- HNRNPA3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs768895205, COSV66820664; called by muse, mutect2, varscan2
- HNRNPM | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57691736; called by muse, mutect2, varscan2
- HOMER1 | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1213548429, COSV56523823; called by muse, mutect2, varscan2
- HOXA1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56065306; called by muse, mutect2, varscan2
- HR | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57190767; called by muse, mutect2, varscan2
- HSDL1 | c.695T>A p.L232* | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as COSV54740299; called by muse, mutect2, varscan2
- HSF2 | c.594G>A p.R198= | Splice Region (SNP) | VAF 46/142 reads (32%) | catalogued as COSV63773418; called by muse, mutect2, varscan2
- HSPA4L | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99612627; called by muse, varscan2
- HTR1B | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs968574182, COSV64051119; called by muse, mutect2, varscan2
- HTR3B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150117061; called by muse, mutect2, varscan2
- HYOU1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs782770261, COSV68215170; called by muse, mutect2, varscan2
- IBTK | c.3521G>T p.S1174I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV60390993, COSV60396452; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.5975C>T p.A1992V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56819448; called by muse, varscan2
- IFI16 | c.2242G>T p.G748W (on ENST00000295809 / NM_001364867.2; = p.G692W on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV55531246, COSV55540165; called by muse, mutect2, varscan2
- IFNA2 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs373475123; called by muse, mutect2, varscan2
- IFT172 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561921; called by muse, mutect2
- IFT81 | c.365dup p.L122Ffs*5 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs756551252; called by mutect2, pindel, varscan2
- IGF2R | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs780405127, COSV63626555; called by muse, mutect2, varscan2
- IGSF9 | c.1147G>A p.A383T (on ENST00000368094 / NM_001135050.2; = p.A367T on NM_020789.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs527258901, COSV63638816; called by muse, mutect2, varscan2
- IK | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1230230454, COSV70257386; called by muse, mutect2, varscan2
- IKZF1 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58781407; called by muse, mutect2, varscan2
- IKZF4 | c.1741del p.E581Sfs*20 | Frame Shift Del (DEL) | VAF 69/289 reads (24%) | catalogued as COSV100008971; called by mutect2, pindel, varscan2
- IL17RD | c.2036T>C p.M679T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV56335282; called by mutect2, varscan2
- IL17REL | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1021422002, COSV58007682; called by muse, mutect2
- IL18R1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV52122719; called by muse, mutect2, varscan2
- IL1RAPL2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61143696; called by muse, mutect2, varscan2
- IMPG1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs200194885, COSV100886419, COSV64054434; called by muse, mutect2, varscan2
- IMPG2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV51973773; called by muse, mutect2, varscan2
- INPP5K | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs138972043, COSV57440002; called by muse, mutect2, varscan2
- INTS12 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60861661; called by muse, mutect2, varscan2
- INTS4 | c.2501C>A p.P834H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59016410; called by muse, mutect2, varscan2
- IQCD | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764014584, COSV55320337; called by muse, mutect2, varscan2
- IRAK3 | c.598dup p.M200Nfs*4 | Frame Shift Ins (INS) | VAF 338/1515 reads (22%) | catalogued as rs776897837; called by mutect2, varscan2
- IRF5 | c.1477C>T p.H493Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1415206663, COSV50856773; called by muse, mutect2, varscan2
- IRGQ | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV60670227; called by muse, mutect2, varscan2
- IRX5 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58058432; called by muse, mutect2, varscan2
- ISL1 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57932247; called by muse, mutect2, varscan2
- ITGB3 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71383455; called by muse, mutect2, varscan2
- ITIH1 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56252217; called by muse, mutect2, varscan2
- ITIH2 | c.1155C>T p.G385= | Splice Region (SNP) | VAF 43/124 reads (35%) | catalogued as COSV64432000; called by muse, mutect2, varscan2
- ITIH5 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs768283912, COSV53660329; called by muse, mutect2, varscan2
- ITPR2 | c.6499A>G p.N2167D | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.277); catalogued as COSV67271372; called by muse, mutect2
- ITPRID1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs747960403, COSV60070407; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs755650243; called by mutect2, pindel
- JAZF1 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52233000; called by muse, mutect2, varscan2
- JMJD1C | c.5846T>C p.M1949T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59512915; called by muse, mutect2, varscan2
- KAZN | c.1772G>A p.S591N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV65714887; called by muse, mutect2, varscan2
- KBTBD3 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.82); catalogued as rs997981454, COSV101595693, COSV73241237; called by muse, mutect2, varscan2
- KBTBD7 | c.699A>G p.I233M | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1316236576, COSV101068050; called by muse, mutect2
- KBTBD7 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771371956, COSV65266158; called by muse, mutect2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 60/186 reads (32%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNA5 | c.866A>G p.H289R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV52904019; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNH6 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs560196120, COSV59000890; called by muse, mutect2, varscan2
- KCNQ5 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.081); catalogued as COSV59650155; called by muse, mutect2, varscan2
- KCTD6 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1232485608, COSV57147392; called by muse, varscan2
- KDM2A | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67081131; called by muse, mutect2, varscan2
- KDM2B | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV65638301; called by muse, mutect2, varscan2
- KDM3B | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV58688180; called by muse, mutect2, varscan2
- KHDRBS3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs779240853, COSV63415069; called by muse, mutect2, varscan2
- KIAA0100 | c.6674C>G p.P2225R | Missense Mutation (SNP) | VAF 230/558 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV56380807; called by muse, mutect2, varscan2
- KIAA1109 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); catalogued as COSV52663029; called by muse, varscan2
- KIAA1217 | c.2368G>A p.V790M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1385829447, COSV56812674; called by muse, mutect2, varscan2
- KIF18A | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200731334, COSV54181261; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF3B | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs370914318; called by muse, mutect2, varscan2
- KIF4A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53452286; called by muse, mutect2, varscan2
- KIF6 | c.1677G>T p.Q559H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54667814; called by mutect2, varscan2
- KIRREL1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63285478; called by muse, mutect2, varscan2
- KLC2 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276648779, COSV57581483; called by muse, mutect2, varscan2
- KLHDC7A | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs369329894, COSV68769058; called by muse, mutect2, varscan2
- KLHL13 | c.1722A>C p.L574F | Missense Mutation (SNP) | VAF 150/484 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.159); catalogued as COSV99451125; called by mutect2, varscan2
- KLHL14 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs773956260, COSV63830709; called by muse, mutect2, varscan2
- KLHL25 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775818150, COSV61994242; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | catalogued as rs749194179; called by mutect2, pindel
- KLHL6 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV58064683, COSV58069508; called by muse, mutect2, varscan2
- KMT2A | c.11708G>A p.R3903H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63282338; called by muse, mutect2, varscan2
- KMT2C | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/266 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV100068273, COSV51522527; called by muse, mutect2
- KMT2D | c.4601G>A p.C1534Y | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56412961; called by muse, mutect2, varscan2
- KMT2D | c.3434C>A p.A1145D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as COSV56412986; called by muse, mutect2, varscan2
- KNDC1 | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs766387008, COSV58831441; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs764099275; called by mutect2, varscan2
- KRI1 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1165742865, COSV57263667; called by muse, mutect2, varscan2
- KRT34 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV67449287; called by muse, mutect2, varscan2
- KRT4 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53408561, COSV99542705; called by muse, varscan2
- KRT78 | c.245del p.G82Afs*5 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs769740852, COSV100467188; called by mutect2, pindel, varscan2
- KRT83 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV53338528; called by muse, mutect2, varscan2
- KRT84 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.402); catalogued as COSV57770657; called by muse, mutect2, varscan2
- KRT85 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57735989; called by muse, mutect2, varscan2
- KRTAP10-4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs374619410; called by muse, mutect2, varscan2
- LAIR1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57306069; called by muse, mutect2, varscan2
- LAMA1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568046765, COSV101055317; called by muse, mutect2
- LAMA3 | c.8042C>T p.S2681L (on ENST00000313654 / NM_198129.4; = p.S1072L on NM_000227.6) | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs371915321, COSV52532872; called by muse, mutect2, varscan2
- LAMC3 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs761037173, COSV63088736; called by muse, mutect2
- LARP4B | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60220033; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs746633076; called by mutect2, varscan2
- LDB1 | c.985G>A p.A329T (on ENST00000425280 / NM_001321612.2; = p.A293T on NM_003893.5) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs768693158, COSV63288659; called by muse, mutect2, varscan2
- LDLRAD4 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100762002; called by muse, mutect2, varscan2
- LGALS2 | c.250-1G>A p.X84_splice | Splice Site (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99312382; called by muse, mutect2
- LGALS8 | c.607G>A p.V203I (on ENST00000341872; = p.V245I on NM_006499.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs555456164, COSV53023623; called by muse, mutect2, varscan2
- LGALS9 | c.812G>A p.R271H (on ENST00000395473 / NM_009587.3; = p.R239H on NM_002308.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs147965169; called by muse, mutect2, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LGI3 | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV60442854, COSV60442949; called by muse, mutect2, varscan2
- LHFPL1 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1462903931, COSV64332955; called by muse, mutect2, varscan2
- LIMA1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs564473856, COSV57964069; called by muse, mutect2, varscan2
- LIMCH1 | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as rs202024828, COSV100574226, COSV58274086; called by muse, mutect2, varscan2
- LINGO1 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62436254; called by muse, mutect2, varscan2
- LINGO4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as COSV63213863; called by muse, mutect2, varscan2
- LIPA | c.577del p.R193Gfs*24 | Frame Shift Del (DEL) | VAF 87/295 reads (29%) | catalogued as COSV51079172; called by mutect2, pindel, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 105/254 reads (41%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBRD1 | c.1330C>A p.L444I (on ENST00000649011; = p.L422I on NM_018368.4) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV65296185, COSV65300438; called by muse, mutect2, varscan2
- LMO7 | c.3301C>T p.H1101Y (on ENST00000357063; = p.H782Y on NM_005358.5) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV58530463; called by muse, mutect2, varscan2
- LMO7 | c.3707G>A p.R1236H (on ENST00000357063; = p.R917H on NM_005358.5) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376159256, COSV58530472; called by muse, mutect2, varscan2
- LMOD1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66171898; called by muse, mutect2, varscan2
- LMX1B | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62738178; called by muse, mutect2, varscan2
- LONRF3 | c.2158A>T p.M720L (on ENST00000371628 / NM_001031855.3; = p.M679L on NM_024778.5) | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59150052; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 48/80 reads (60%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756683733, COSV54502603; called by muse, varscan2
- LRP1 | c.12818C>T p.A4273V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs763058234, COSV54502613; called by muse, mutect2, varscan2
- LRP11 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs374603588, COSV53333027; called by muse, mutect2, varscan2
- LRP2 | c.1793G>A p.G598D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55541707; called by muse, mutect2, varscan2
- LRRC8A | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV52184203; called by muse, mutect2, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 56/180 reads (31%) | catalogued as rs762972819; called by mutect2, pindel
- LRRIQ3 | c.1134del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 105/375 reads (28%) | catalogued as rs751977298; called by mutect2, pindel, varscan2
- LRRN3 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV57817720; called by muse, mutect2, varscan2
- LRRTM4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV69139056; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- LURAP1L | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV59983643; called by muse, mutect2, varscan2
- LVRN | c.1267G>T p.G423* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV63496090; called by muse, mutect2, varscan2
- LYN | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.24); catalogued as COSV72922932; called by muse, mutect2, varscan2
- LYRM9 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV66958792; called by muse, mutect2, varscan2
- LYZL1 | c.114-1G>A p.X38_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as COSV64966093; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 54/450 reads (12%) | catalogued as rs753028254; called by mutect2, pindel, varscan2
- M6PR | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749091380, COSV50002592; called by muse, mutect2, varscan2
- MACROD2 | c.1049G>A p.R350H (on ENST00000642719; = p.R322H on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs763015539, COSV53948315; called by muse, varscan2
- MADD | c.4742A>G p.H1581R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV57023445; called by muse, mutect2, varscan2
- MAG | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs201990546, COSV62702475; called by muse, mutect2, varscan2
- MAGED1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58514555; called by muse, mutect2, varscan2
- MAGEL2 | c.2874G>T p.W958C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100045904, COSV58565986; called by muse, mutect2, varscan2
- MAML3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs376616820; called by muse, mutect2, varscan2
- MAN2B1 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764964301, COSV55470236; called by muse, mutect2, varscan2
- MAN2B1 | c.2114C>A p.P705Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.223); catalogued as COSV55470245; called by muse, mutect2, varscan2
- MANBA | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56962990; called by muse, mutect2, varscan2
- MAP1B | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778270951, COSV57094018; called by muse, mutect2, varscan2
- MAP2K4 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV62255114; called by muse, mutect2, varscan2
- MAP3K13 | c.2502-2A>G p.X834_splice | Splice Site (SNP) | VAF 48/154 reads (31%) | catalogued as COSV99406244; called by muse, mutect2, varscan2
- MAP3K21 | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64043450; called by muse, mutect2, varscan2
- MAP3K3 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51991195; called by muse, mutect2, varscan2
- MAP7D2 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65525673; called by muse, mutect2, varscan2
- MAPK6 | c.533T>C p.M178T | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as COSV55928904; called by muse, mutect2, varscan2
- MARVELD2 | c.1578del p.E527Nfs*6 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV57780447; called by mutect2, varscan2
- MAST4 | c.5950G>A p.E1984K (on ENST00000403625 / NM_001164664.2; = p.E1795K on NM_015183.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as rs767219421, COSV55116435; called by muse, mutect2, varscan2
- MAST4 | c.7264C>T p.P2422S (on ENST00000403625 / NM_001164664.2; = p.P2233S on NM_015183.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); catalogued as rs927889745, COSV55116453; called by muse, varscan2
- MASTL | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60909551; called by muse, mutect2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751885186, COSV53998320; called by muse, mutect2, varscan2
- MBD5 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV68695819; called by muse, mutect2, varscan2
- MCF2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 131/378 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58478163; called by muse, mutect2, varscan2
- MCF2L | c.3041A>G p.K1014R (on ENST00000375608; = p.K982R on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV56175567; called by muse, mutect2, varscan2
- MCF2L2 | c.1095dup p.L366Tfs*45 | Frame Shift Ins (INS) | VAF 41/156 reads (26%) | catalogued as rs748576542; called by mutect2, pindel, varscan2
- MCHR1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as rs765877994, COSV50760354; called by muse, mutect2, varscan2
- MCM3AP | c.3091C>T p.Q1031* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52436488; called by muse, mutect2, varscan2
- MCTS1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV64892249; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 57/185 reads (31%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MDN1 | c.3808A>G p.I1270V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1379435029, COSV65517476; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 47/91 reads (52%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED12 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61332408, COSV61353101; called by muse, mutect2, varscan2
- MED14 | c.348G>A p.A116= | Splice Region (SNP) | VAF 39/104 reads (38%) | catalogued as COSV61355894; called by muse, mutect2, varscan2
- MED4 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51638683; called by muse, mutect2, varscan2
- METTL22 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs201872412, COSV50837403; called by muse, mutect2, varscan2
- METTL26 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142689363; called by muse, mutect2, varscan2
- MEX3C | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.952); catalogued as COSV68529600; called by muse, mutect2, varscan2
- MFSD8 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755384900, COSV56550444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGA | c.7126T>C p.S2376P (on ENST00000219905 / NM_001164273.1; = p.S2167P on NM_001080541.2) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54949258; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as COSV54098507; called by mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 124/237 reads (52%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MKX | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65391525; called by muse, mutect2, varscan2
- MLLT6 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1364789691; called by muse, mutect2, varscan2
- MMP1 | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59509430; called by muse, mutect2, varscan2
- MMP11 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs1367281177, COSV53155441; called by muse, mutect2, varscan2
- MMP15 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356216183, COSV54678756; called by muse, mutect2
- MMP9 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63433778; called by muse, mutect2, varscan2
- MON2 | c.3792_3795del p.T1265Lfs*11 | Frame Shift Del (DEL) | VAF 44/200 reads (22%) | catalogued as rs1235291787; called by pindel, varscan2
- MORC1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99225294; called by muse, mutect2, varscan2
- MOSPD1 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV66189132; called by muse, mutect2, varscan2
- MOV10L1 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167535; called by muse, mutect2, varscan2
- MPIG6B | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV65389327; called by muse, mutect2, varscan2
- MRAP | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs781703497, COSV57936395; called by muse, mutect2, varscan2
- MRPL46 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56899298; called by muse, mutect2, varscan2
1,364 further variants in this file (868 protein-altering or splice-affecting, 443 silent, 53 other) are not listed here.
